TARGET case TARGET-40-0A4I0W — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf48d859-9c1d-5421-9140-5a0ca7292df7

Demographics
Sex at birth: male; Race: asian; Age at index: 20 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 20.1 years (7,330 days); Year of diagnosis: 2006; Metastasis at diagnosis: No Metastasis; Days to last follow up: 683 days (1.9 years).
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Methotrexate.
   Treatment given: Therapeutic agents: Platinum.

Follow-up (1 entry)
- Days to follow up: 683 days (1.9 years); Event-free: no event (relapse, second malignancy or death) recorded through day 683; Year of follow up: 2010.

Biospecimens (2 samples)
- Sample TARGET-40-0A4I0W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4I0W-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 683
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Therapy: Adria/Plat/MTX
